Somatic mutation profile of tumor specimen e9d416e7-f661-400a-896e-388545 (aliquot e9d416e7-f661-400a-896e-388545_D6) from CPTAC case 04OV037, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen e9d416e7-f661-400a-896e-388545: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bb132c6-a4f5-4564-8d2e-97096272a6eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5eef476a-4c66-43fe-bd3e-9d4aa5 (Blood Derived Normal), aliquot 5eef476a-4c66-43fe-bd3e-9d4aa5_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bdfab48-a140-4586-b51f-a4a47d0bacbd

The open-access MAF lists 226 somatic variants for this specimen: 163 protein-altering or splice-affecting, 40 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 40, Nonsense Mutation 13, Intron 8, Frame Shift Del 8, 3'UTR 6, In Frame Del 5, Splice Site 4, 5'UTR 3, RNA 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 526/660 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.3991C>G p.P1331A (on ENST00000326724 / NM_001080395.3; = p.P1228A on NM_004920.2) | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs755987684; called by muse, mutect2, varscan2
- ABCA3 | c.2172C>A p.D724E | Missense Mutation (SNP) | VAF 341/515 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV57055946; called by muse, mutect2, varscan2
- ACOT4 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58336174; called by muse, mutect2
- ASTL | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as rs769275452, COSV60905330; called by muse, mutect2, varscan2
- BAZ2B | c.3677G>A p.S1226N | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.643); catalogued as rs1323826051; called by muse, mutect2, varscan2
- C21orf62 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 92/343 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as rs1435090151; called by muse, mutect2, varscan2
- CFAP61 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs867292904, COSV104369129, COSV99071636; called by muse, mutect2, varscan2
- COL17A1 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 99/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301380443, COSV100793291; called by muse, mutect2, varscan2
- FOXM1 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs753788611, COSV100700776; called by muse, mutect2, varscan2
- GLI2 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 192/1042 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.333); catalogued as rs907487597; called by muse, mutect2, varscan2
- HELZ | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs780497369; called by muse, mutect2, varscan2
- HTR5A | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 308/612 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV55283775; called by muse, mutect2, varscan2
- IL32 | c.641C>A p.A214D (on ENST00000396890 / NM_001308078.4; = p.A168D on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as COSV50406192; called by muse, mutect2, varscan2
- INTS2 | c.6+7G>T | Splice Region (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99247594; called by muse, mutect2, varscan2
- KRT33B | c.387del p.Q130Rfs*40 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as COSV52442426; called by mutect2, pindel, varscan2
- LRBA | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV63961040; called by muse, mutect2, varscan2
- MARCO | c.648A>C p.Q216H | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV59055750; called by muse, varscan2
- METTL4 | c.610A>G p.M204V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs747378722; called by muse, mutect2, varscan2
- MEX3A | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs1163826131; called by muse, mutect2, varscan2
- MYH13 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV52838616; called by muse, mutect2
- OR4D11 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 103/370 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV57585139; called by muse, mutect2, varscan2
- PDZRN3 | c.2294G>C p.R765P | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55206860; called by muse, mutect2
- PKD1L1 | c.7630C>G p.R2544G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs772221646, COSV51843162; called by muse, mutect2, varscan2
- PLEKHG4 | c.3317G>T p.C1106F | Missense Mutation (SNP) | VAF 175/599 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1339423577; called by muse, mutect2, varscan2
- PNLIPRP1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs782005597; called by muse, mutect2, varscan2
- PPP1R32 | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100087686, COSV100087772, COSV58544996; called by muse, mutect2, varscan2
- PPP1R3B | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs764634311, COSV60099711; called by muse, mutect2
- PRCC | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs755536156; called by muse, mutect2, varscan2
- SLC14A1 | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV58934098; called by muse, mutect2
- SLC25A12 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55533538; called by muse, mutect2, varscan2
- SLC45A1 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 334/669 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as rs1186846577, COSV57099890; called by muse, mutect2, varscan2
- SPATS2 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 89/336 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs767444674; called by muse, mutect2, varscan2
- SPEN | c.2986G>C p.E996Q | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV65361487; called by muse, mutect2, varscan2
- SRPK3 | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.651); catalogued as rs372984891; called by muse, mutect2, varscan2
- STRN | c.2332G>T p.V778F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55747185; called by muse, mutect2
- STYXL2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV54808923; called by muse, mutect2, varscan2
- SUCNR1 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751816; called by muse, mutect2
- THEMIS | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV100965377; called by muse, mutect2
- THOC2 | c.3981G>C p.E1327D | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55550828; called by muse, mutect2, varscan2
- TRIP10 | c.1567G>A p.D523N (on ENST00000313244 / NM_001288962.2; = p.D467N on NM_004240.4) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as rs569983980; called by muse, mutect2, varscan2
- TRNT1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1428349978; called by muse, mutect2, varscan2
- TRO | c.3773G>A p.G1258D | Missense Mutation (SNP) | VAF 163/336 reads (49%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.222); catalogued as COSV99437225; called by muse, mutect2, varscan2
- TSHZ2 | c.2706C>G p.N902K | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100296911; called by muse, mutect2, varscan2
- VCAN | c.4265A>G p.K1422R | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV54113072; called by muse, mutect2, varscan2
- ZNF709 | c.1289G>T p.S430I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as rs879021396; called by muse, mutect2, varscan2
- AACS | c.491A>T p.E164V | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- AATF | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADCK5 | c.357C>G p.Y119* | Nonsense Mutation (SNP) | VAF 108/585 reads (18%) | called by muse, mutect2, varscan2
- APBA1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP25 | c.735G>T p.E245D (on ENST00000409202 / NM_001007231.3; = p.E237D on NM_014882.3) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ASTN1 | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATRN | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2
- BRCA1 | c.851del p.Q284Rfs*14 | Frame Shift Del (DEL) | VAF 40/85 reads (47%) | called by mutect2, pindel, varscan2
- CC2D2B | c.389A>G p.Q130R (on ENST00000646931 / NM_001349008.3; = p.Q122R on NM_001130446.3) | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCDC80 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 176/733 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD47 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CDH18 | c.761del p.V254Afs*5 | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | called by mutect2, pindel, varscan2
- CDK2 | c.792+1G>C p.X264_splice | Splice Site (SNP) | VAF 54/250 reads (22%) | called by muse, mutect2, varscan2
- CFAP251 | c.1817A>C p.K606T | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CNDP1 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); called by muse, varscan2
- CPNE5 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- CYP4F2 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DENND4A | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 77/106 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND4A | c.193T>G p.C65G | Missense Mutation (SNP) | VAF 69/109 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DERA | c.260T>A p.L87* | Nonsense Mutation (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- DIDO1 | c.3739T>A p.C1247S | Missense Mutation (SNP) | VAF 56/403 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.8633C>A p.A2878D (on ENST00000409039; = p.A2817D on NM_207437.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAH2 | c.8973G>T p.K2991N | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DNAJB1 | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK11 | c.5378C>A p.S1793* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- EPS15 | c.1516A>G p.N506D | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ERBB4 | c.2972A>T p.D991V | Missense Mutation (SNP) | VAF 86/140 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- FAM120C | c.2980C>T p.H994Y | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM214B | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 54/230 reads (23%) | called by muse, mutect2
- FAM83C | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 160/730 reads (22%) | called by muse, mutect2, varscan2
- FCSK | c.1976A>G p.K659R | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM2 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- FSIP1 | c.727A>T p.K243* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- GLI2 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 193/1040 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- GLI4 | c.1123C>A p.R375S | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2
- GLS2 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GRIN1 | c.1287C>A p.D429E | Missense Mutation (SNP) | VAF 67/477 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRXCR1 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- HACD4 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- HACE1 | c.1948T>A p.L650I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HCAR3 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HECTD4 | c.1726C>G p.Q576E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IFT140 | c.1172A>T p.N391I | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- IGFBPL1 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- INPP5F | c.1660A>G p.K554E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KCNH1 | c.805T>A p.F269I | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNT2 | c.1687T>G p.F563V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIF3B | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2A | c.10147A>C p.I3383L | Missense Mutation (SNP) | VAF 86/359 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMB4 | c.2310G>C p.K770N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LAMC3 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 368/988 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LBP | c.97A>G p.R33G | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRRC63 | c.831A>C p.E277D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- LUM | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYAR | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MACROH2A2 | c.984_1010del p.Q328_A336del | In Frame Del (DEL) | VAF 41/192 reads (21%) | called by mutect2, pindel
- MAGEC1 | c.2450_2458del p.F817_S819del | In Frame Del (DEL) | VAF 55/435 reads (13%) | called by mutect2, pindel
- MORC4 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 11/389 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- MRPS27 | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MTUS2 | c.3587T>C p.V1196A (on ENST00000612955 / NM_001366650.1; = p.V175A on NM_015233.6) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC16 | c.38893A>G p.N12965D | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MYO15A | c.9670_9672del p.L3224del | In Frame Del (DEL) | VAF 155/332 reads (47%) | called by mutect2, pindel, varscan2
- NAB1 | c.816T>A p.H272Q | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAV1 | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- NDUFS1 | c.965C>G p.A322G | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- NEB | c.9313G>A p.V3105I | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NKD1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 68/218 reads (31%) | called by muse, mutect2, varscan2
- NOC2L | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 80/575 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NOTCH4 | c.1572C>A p.N524K | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- NPAS2 | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NRAP | c.3187-5_3196del p.X1063_splice (on ENST00000359988 / NM_001322945.2; = p.X1028_splice on NM_006175.4) | Splice Site (DEL) | VAF 55/133 reads (41%) | called by mutect2, pindel, varscan2
- NUP153 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- OR1G1 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 104/213 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- OR2F2 | c.609_621del p.S203Rfs*2 | Frame Shift Del (DEL) | VAF 90/700 reads (13%) | called by mutect2, pindel, varscan2
- PCK2 | c.1738G>C p.G580R | Missense Mutation (SNP) | VAF 186/744 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PCMTD2 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PDZD2 | c.7721C>A p.S2574* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2
- PEAK1 | c.3576_3619del p.N1193Qfs*6 | Frame Shift Del (DEL) | VAF 89/274 reads (32%) | called by mutect2, pindel, varscan2
- PHF3 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PLD1 | c.1889T>G p.L630* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- PLEKHO1 | c.1098G>C p.W366C | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PNPLA1 | c.1408A>G p.K470E (on ENST00000394571 / NM_001374623.1; = p.K375E on NM_173676.2) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- POM121L12 | c.292_309delinsGAGACA p.R98_P103delinsET | In Frame Del (DEL) | VAF 83/535 reads (16%) | called by pindel, varscan2*
- PRPF19 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PRR14L | c.2210C>A p.P737Q | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PTCH1 | c.2478C>A p.F826L | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PTPRD | c.726_768del p.T243Vfs*11 | Frame Shift Del (DEL) | VAF 105/531 reads (20%) | called by mutect2, pindel
- RASAL2 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RFTN2 | c.439-2A>C p.X147_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- RNF157 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPSA | c.111C>G p.Y37* | Nonsense Mutation (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
- RPUSD4 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.268); called by muse, mutect2
- SALL3 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2
- SCAF1 | c.3215A>T p.D1072V | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- SFMBT2 | c.2569C>T p.L857F | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC35A2 | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 113/531 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SMC4 | c.688-19_699del p.X230_splice | Splice Site (DEL) | VAF 12/120 reads (10%) | called by mutect2, pindel
- ST14 | c.1158C>G p.Y386* | Nonsense Mutation (SNP) | VAF 90/279 reads (32%) | called by muse, mutect2
- SUCNR1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SULT6B1 | c.775C>G p.R259G (on ENST00000535679 / NM_001367551.1; = p.R221G on NM_001032377.2) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANC2 | c.5329_5360del p.S1777* | Frame Shift Del (DEL) | VAF 71/451 reads (16%) | called by mutect2, pindel, varscan2
- TBC1D17 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 156/425 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TIAM2 | c.3914A>T p.D1305V | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMMDC1 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TMEM108 | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- TOP2B | c.3758C>T p.A1253V (on ENST00000264331 / NM_001330700.2; = p.A1248V on NM_001068.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TRAV3 | c.247_258del p.E83_F86del | In Frame Del (DEL) | VAF 46/336 reads (14%) | called by mutect2, pindel, varscan2
- TTLL2 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- WSCD1 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZBTB22 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 145/601 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZBTB47 | c.1708C>A p.H570N | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.329); called by mutect2, varscan2
- ZCCHC4 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZEB1 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ZNF160 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.5038del p.C1680Afs*31 (on ENST00000437464; = p.C1708Afs*31 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 128/512 reads (25%) | called by mutect2, pindel, varscan2
- ZYG11B | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS8 | c.273C>A p.T91= | Silent (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- AL645922.1 | c.2088G>C p.G696= | Silent (SNP) | VAF 156/687 reads (23%) | called by muse, mutect2, varscan2
- ANXA6 | c.192C>G p.S64= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as COSV62905690, COSV62908553; called by muse, mutect2, varscan2
- COL7A1 | c.651G>T p.T217= | Silent (SNP) | VAF 35/692 reads (5%) | called by muse, mutect2
- CSMD2 | c.8376G>C p.V2792= | Silent (SNP) | VAF 77/220 reads (35%) | called by muse, mutect2, varscan2
- DCLRE1B | c.1299G>T p.V433= | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- DNAH6 | c.3924G>A p.R1308= | Silent (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- EIF3A | c.4077G>A p.E1359= | Silent (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- FMR1NB | c.651A>G p.L217= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- GPR61 | c.708C>T p.R236= | Silent (SNP) | VAF 47/527 reads (9%) | catalogued as rs145896093; called by muse, mutect2
- HIVEP2 | c.4014C>A p.I1338= | Silent (SNP) | VAF 405/694 reads (58%) | called by muse, mutect2, varscan2
- IQSEC2 | c.2073T>A p.S691= (on ENST00000642864 / NM_001111125.3; = p.S486= on NM_015075.2) | Silent (SNP) | VAF 75/358 reads (21%) | called by muse, mutect2, varscan2
- ITGB6 | c.300C>T p.D100= | Silent (SNP) | VAF 87/223 reads (39%) | catalogued as rs771795596; called by muse, mutect2, varscan2
- JMJD4 | c.282C>T p.F94= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs1173124119; called by muse, mutect2, varscan2
- LMO4 | c.93G>T p.A31= | Silent (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- LTBP3 | c.1971G>A p.S657= | Silent (SNP) | VAF 179/672 reads (27%) | catalogued as rs372794947; called by muse, mutect2, varscan2
- LY75 | c.1503T>C p.C501= | Silent (SNP) | VAF 4/81 reads (5%) | called by muse, mutect2
- MED12L | c.5088G>T p.V1696= | Silent (SNP) | VAF 38/211 reads (18%) | called by muse, mutect2, varscan2
- MME | c.1284G>T p.V428= | Silent (SNP) | VAF 290/456 reads (64%) | called by muse, mutect2, varscan2
- MOV10L1 | c.2313T>A p.P771= | Silent (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- MTARC1 | c.492C>G p.A164= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV65055758; called by muse, mutect2, varscan2
- NECTIN2 | c.294T>C p.P98= | Silent (SNP) | VAF 95/300 reads (32%) | called by muse, mutect2, varscan2
- NLRP5 | c.1980G>T p.G660= | Silent (SNP) | VAF 97/243 reads (40%) | catalogued as COSV101173315, COSV66763775, COSV66764886; called by muse, mutect2, varscan2
- NR1D1 | c.528C>A p.S176= | Silent (SNP) | VAF 48/234 reads (21%) | called by muse, mutect2, varscan2
- NYAP2 | c.60C>G p.L20= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99797968; called by muse, mutect2, varscan2
- ODF4 | c.231C>T p.R77= | Silent (SNP) | VAF 91/404 reads (23%) | called by muse, mutect2, varscan2
- PPP1R14A | c.90G>C p.L30= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- PRODH2 | c.1554G>T p.L518= (on ENST00000301175; = p.L442= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- PTGFR | c.1020T>C p.N340= | Silent (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1512C>T p.S504= | Silent (SNP) | VAF 92/359 reads (26%) | called by muse, mutect2, varscan2
- SLC24A2 | c.402G>A p.A134= | Silent (SNP) | VAF 243/654 reads (37%) | catalogued as rs757158542; called by muse, mutect2, varscan2
- SLC7A2 | c.675C>T p.L225= (on ENST00000494857 / NM_001370338.1; = p.L265= on NM_003046.6) | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- SSTR2 | c.652C>T p.L218= | Silent (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- TAS1R1 | c.639G>T p.L213= | Silent (SNP) | VAF 260/823 reads (32%) | called by muse, mutect2, varscan2
- TCF20 | c.1611A>C p.L537= | Silent (SNP) | VAF 81/418 reads (19%) | called by muse, mutect2, varscan2
- TEKT5 | c.570C>T p.A190= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV99295725; called by muse, mutect2, varscan2
- THEM5 | c.207G>T p.L69= | Silent (SNP) | VAF 100/602 reads (17%) | called by muse, mutect2, varscan2
- TNK2 | c.2286C>T p.G762= | Silent (SNP) | VAF 39/47 reads (83%) | catalogued as rs1056539851; called by muse, mutect2, varscan2
- TRADD | c.420A>T p.L140= | Silent (SNP) | VAF 72/183 reads (39%) | called by muse, mutect2, varscan2
- WDR87 | c.1161A>G p.V387= | Silent (SNP) | VAF 92/278 reads (33%) | called by muse, mutect2, varscan2
- ASAH2 | c.510+2671C>T | Intron (SNP) | VAF 17/176 reads (10%) | catalogued as rs1214179015; called by muse, mutect2
- CAMKK2 | c.*2T>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- CCDC187 | c.*2656T>A | 3'UTR (SNP) | VAF 17/536 reads (3%) | called by muse, mutect2
- EPOR | chr19:11384325 C>G | 5'Flank (SNP) | VAF 34/110 reads (31%) | catalogued as rs1026928348; called by muse, mutect2, varscan2
- ERBB4 | c.82+112136del | Intron (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- FRMD8P1 | n.205G>A | RNA (SNP) | VAF 78/333 reads (23%) | catalogued as rs1439727730; called by muse, mutect2, varscan2
- GMPR2 | c.207+625T>C | Intron (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- HUWE1 | c.1490-775T>G | Intron (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- KCNE3 | c.-21C>T | 5'UTR (SNP) | VAF 47/350 reads (13%) | catalogued as rs1288516985; called by muse, mutect2, varscan2
- LINC01193 | n.1429T>A | RNA (SNP) | VAF 66/330 reads (20%) | called by muse, mutect2, varscan2
- MAP1S | c.119-539G>C | Intron (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397724 T>C | 3'Flank (SNP) | VAF 106/342 reads (31%) | called by muse, mutect2, varscan2
- NPIPA1 | c.642+49G>T | Intron (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- NRP2 | c.2440+9657G>A | Intron (SNP) | VAF 93/327 reads (28%) | catalogued as COSV55922922; called by muse, mutect2, varscan2
- POLA1 | c.2947-21069G>A | Intron (SNP) | VAF 130/281 reads (46%) | called by muse, mutect2, varscan2
- PRRT1 | c.*378C>G | 3'UTR (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791902 A>G | 3'Flank (SNP) | VAF 367/510 reads (72%) | catalogued as rs777882463; called by muse, mutect2, varscan2
- SOCS2 | c.-28C>T | 5'UTR (SNP) | VAF 20/356 reads (6%) | called by muse, mutect2
- SSPOP | n.10545C>A | RNA (SNP) | VAF 61/579 reads (11%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2141C>G | 3'UTR (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53025278; called by muse, mutect2, varscan2
- TXNDC9 | c.-15G>A | 5'UTR (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1474G>T | 3'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- ZSCAN21 | c.*22G>C | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
